Somatic mutation profile of tumor specimen TCGA-ZF-AA52-01A (aliquot TCGA-ZF-AA52-01A-12D-A391-08) from TCGA case TCGA-ZF-AA52, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.0 years (25,579 days).
Specimen TCGA-ZF-AA52-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6719311f-96d8-49d5-b506-9c535ca2372b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA52-10A (Blood Derived Normal), aliquot TCGA-ZF-AA52-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e8ec974-4a55-4b28-9fa4-fee0a244f876

The open-access MAF lists 128 somatic variants for this specimen: 90 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 35, Nonsense Mutation 5, Frame Shift Ins 2, 5'Flank 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCG2 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV52945421; called by muse, mutect2, varscan2
- ACSS1 | c.1564T>C p.F522L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100053746; called by muse, mutect2
- ACTR3B | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 20/219 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV99754073; called by muse, mutect2
- ADGRG6 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as rs368529000, COSV51587588; called by muse, mutect2, varscan2
- AHCTF1 | c.6403C>T p.R2135W (on ENST00000366508; = p.R2109W on NM_015446.5) | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs755918895, COSV58246736; called by muse, mutect2, varscan2
- AREG | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99144390; called by muse, mutect2, varscan2
- ATP13A4 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV55068605; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1676A>G p.H559R | Missense Mutation (SNP) | VAF 80/203 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1345430229, COSV52872642; called by muse, mutect2, varscan2
- ATP6V1D | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV53599375; called by muse, mutect2, varscan2
- ATRX | c.3734C>T p.S1245L | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV64870889, COSV64872646; called by muse, mutect2, varscan2
- BPIFB6 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62755027; called by muse, mutect2
- CACNA1H | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369630836; called by muse, mutect2, varscan2
- CHD9 | c.2975G>A p.R992Q | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs374505230; called by muse, mutect2
- CILK1 | c.1730G>A p.R577K (on ENST00000350082 / NM_001375397.1; = p.R570K on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs906677297, COSV63154029; called by muse, mutect2
- CNTNAP4 | c.3751A>T p.I1251F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs756282864, COSV56676695; called by muse, varscan2
- CTNNA3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs866472317, COSV101049853, COSV65574596; called by muse, mutect2
- CWC27 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV66885530; called by muse, mutect2, varscan2
- DDIT4L | c.359A>C p.K120T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.534); catalogued as COSV56767235; called by muse, mutect2, varscan2
- DEPDC7 | c.182G>A p.R61Q (on ENST00000241051 / NM_001077242.2; = p.R52Q on NM_139160.2) | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs200057806; called by muse, mutect2, varscan2
- DMTF1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58684662; called by muse, mutect2, varscan2
- DOCK6 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs1270538769, COSV99625586; called by muse, mutect2, varscan2
- ECH1 | c.841T>C p.Y281H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55489065; called by muse, mutect2, varscan2
- ERAP2 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs754839003, COSV65939477; called by muse, mutect2, varscan2
- ERN2 | c.935C>G p.P312R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV56833112; called by muse, mutect2
- FANCF | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as COSV59416085; called by muse, mutect2, varscan2
- FCER1A | c.702G>C p.L234F | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV63667061; called by muse, mutect2, varscan2
- GAB2 | c.1609G>A p.D537N (on ENST00000361507 / NM_080491.3; = p.D499N on NM_012296.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.734); catalogued as rs780638233, COSV60867289; called by muse, mutect2, varscan2
- GOLIM4 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58329393; called by muse, mutect2
- H2BC11 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60362012; called by muse, mutect2
- HMCN1 | c.16478G>C p.R5493T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54895074; called by muse, mutect2, varscan2
- HSD17B12 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99550682; called by muse, mutect2, varscan2
- IGSF10 | c.3058G>A p.G1020R | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs865939816, COSV56784379; called by muse, mutect2, varscan2
- IRX1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs1417488119, COSV57357969; called by muse, mutect2
- KALRN | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99564409; called by muse, mutect2
- KIRREL2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767203597, COSV52875861; called by muse, mutect2, varscan2
- LRRC36 | c.1121A>G p.H374R | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.61); catalogued as COSV52079287; called by muse, mutect2, varscan2
- MTMR3 | c.2590C>T p.H864Y | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.123); catalogued as COSV60303718; called by muse, mutect2
- MUTYH | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV58344026; called by muse, mutect2
- MYOCD | c.2287A>G p.K763E | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs766441876, COSV58502415, COSV58508701; called by muse, mutect2, varscan2
- NAGPA | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | PolyPhen possibly damaging (0.896); catalogued as COSV56569768; called by muse, mutect2, varscan2
- NES | c.3190G>C p.E1064Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV63960846, COSV63962693; called by muse, mutect2
- NLRP3 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100276058; called by muse, mutect2
- NPAP1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV61506274; called by muse, mutect2, varscan2
- NPR1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64117530; called by muse, mutect2, varscan2
- NRP1 | c.542A>C p.K181T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55165035; called by muse, mutect2, varscan2
- OR5AC2 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as rs193920759, COSV62279352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5H1 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63402245, COSV63402524, COSV63403532; called by muse, mutect2, varscan2
- OR8K3 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 4/84 reads (5%) | catalogued as COSV100449782, COSV57133441; called by muse, mutect2
- OR8K3 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100449647, COSV57131334; called by muse, mutect2
- PAPPA2 | c.2207G>A p.G736E | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62777018; called by muse, mutect2, varscan2
- PCNX1 | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV53093256; called by muse, mutect2
- PDCD2 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780538358, COSV51341119; called by muse, mutect2, varscan2
- PHKA1 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59805007, COSV59812732; called by muse, mutect2, varscan2
- PIH1D2 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54776961; called by muse, mutect2
- PPP1R12B | c.497A>C p.E166A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61116125; called by muse, mutect2, varscan2
- PRDM2 | c.2731A>G p.R911G | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52445676; called by muse, mutect2, varscan2
- PSMD6 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as COSV55759465; called by muse, mutect2
- PUM1 | c.1712C>T p.A571V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1350534123, COSV57084412; called by muse, mutect2
- RAB11FIP3 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV51931836, COSV99240630; called by muse, mutect2, varscan2
- REPS2 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV58181320; called by muse, mutect2, varscan2
- RNF169 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV55131929; called by muse, mutect2
- RTCA | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as rs756355302, COSV99559871; called by muse, mutect2, varscan2
- SEPTIN12 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs886130124, COSV51616691; called by muse, mutect2
- SERPINB5 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV66975330; called by muse, mutect2, varscan2
- SLC6A5 | c.1417C>G p.Q473E | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54225060, COSV54227109, COSV54232411; called by muse, mutect2, varscan2
- SMC4 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as COSV61004424; called by muse, mutect2
- STK17B | c.837G>A p.E279= | Splice Region (SNP) | VAF 9/47 reads (19%) | catalogued as COSV55828015; called by muse, mutect2, varscan2
- STK38 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV100007193, COSV100007305; called by muse, mutect2
- TBX4 | c.854C>G p.S285* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV53606031, COSV53609743; called by muse, mutect2, varscan2
- TMF1 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.107); catalogued as rs762003130, COSV68374090; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3686C>G p.S1229C | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs139978039; called by muse, mutect2
- TNS1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336032074, COSV50699380; called by muse, mutect2, varscan2
- TP53 | c.532dup p.H178Pfs*3 | Frame Shift Ins (INS) | VAF 24/84 reads (29%) | catalogued as COSV99408054; called by mutect2, pindel, varscan2
- TP53BP1 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as rs1214715472, COSV55499808; called by muse, mutect2, varscan2
- TRAPPC10 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1158803731, COSV52377732; called by muse, mutect2
- TRIB2 | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99331115; called by muse, mutect2
- UBQLN1 | c.871-1G>A p.X291_splice | Splice Site (SNP) | VAF 5/28 reads (18%) | catalogued as COSV57407566, COSV57408902; called by muse, mutect2, varscan2
- XKR5 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs769855267, COSV68398112; called by muse, mutect2
- ZMAT4 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1337710894, COSV52696908; called by muse, mutect2, varscan2
- ZNF233 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV61933514; called by muse, mutect2, varscan2
- ZNF641 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV56390018; called by muse, mutect2, varscan2
- ZNF665 | c.1402C>T p.Q468* (on ENST00000600412; = p.Q533* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/184 reads (11%) | catalogued as COSV101128370; called by muse, mutect2, varscan2
- ZNF708 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV63607296; called by muse, mutect2, varscan2
- ZNF75D | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV66132659; called by muse, mutect2, varscan2
- AGPAT1 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.348); called by muse, mutect2
- BCOR | c.4189_4194del p.F1397_R1398del (on ENST00000378444 / NM_001123385.2; = p.F1363_R1364del on NM_017745.6) | In Frame Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- FEZ1 | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- HMGCS2 | c.1350dup p.S451Lfs*8 | Frame Shift Ins (INS) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- NUP42 | c.165del p.N56Mfs*66 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, varscan2
- AGPAT3 | c.159C>T p.L53= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs760861867, COSV52371437; called by muse, mutect2, varscan2
- CACNA1I | c.2808C>T p.L936= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- CACNG3 | c.738C>T p.D246= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV50066774; called by muse, mutect2
- COL8A1 | c.873T>C p.A291= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99657766; called by muse, mutect2
- DSG1 | c.2811G>C p.L937= | Silent (SNP) | VAF 17/191 reads (9%) | catalogued as COSV57134806; called by muse, mutect2
- FER1L6 | c.2172C>G p.L724= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as COSV67549521; called by muse, mutect2, varscan2
- FLG | c.11244C>T p.H3748= | Silent (SNP) | VAF 28/392 reads (7%) | catalogued as rs377272004, COSV64240729; called by muse, mutect2
- FLG | c.9336A>G p.G3112= | Silent (SNP) | VAF 114/285 reads (40%) | catalogued as COSV64240733; called by muse, mutect2, varscan2
- GPRASP1 | c.2823C>T p.F941= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV64355421; called by muse, mutect2, varscan2
- KIAA0319L | c.195G>A p.L65= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as COSV57844874; called by muse, mutect2
- LMTK2 | c.3675C>T p.L1225= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs777527383, COSV51997333; called by mutect2, varscan2
- MC4R | c.312C>T p.I104= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV55351899; called by muse, mutect2
- MTAP | c.645C>T p.I215= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs144828400; called by muse, mutect2, varscan2
- MYT1 | c.510C>T p.N170= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV60504635; called by muse, mutect2
- PCDH7 | c.2502C>T p.G834= | Silent (SNP) | VAF 18/133 reads (14%) | called by muse, mutect2, varscan2
- PCDHA13 | c.144C>T p.I48= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs868915208, COSV56495461; called by muse, mutect2
- PCDHB12 | c.522G>A p.P174= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as rs781930477, COSV53395669; called by muse, mutect2, varscan2
- PCDHGC3 | c.42G>C p.G14= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV52749738; called by muse, mutect2, varscan2
- PKN1 | c.2046C>T p.F682= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs373941894; called by muse, mutect2, varscan2
- PPOX | c.1134G>A p.E378= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs753986672, COSV57088013; called by muse, mutect2, varscan2
- RYR1 | c.10701G>A p.P3567= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs771866213, COSV62095323; called by muse, mutect2, varscan2
- SCARB1 | c.534G>A p.E178= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs1032908728, COSV55546797; called by muse, mutect2, varscan2
- SEL1L | c.1707C>T p.G569= | Silent (SNP) | VAF 31/170 reads (18%) | catalogued as rs753470397, COSV60919187; called by muse, mutect2, varscan2
- SP100 | c.162C>T p.F54= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV50977786; called by muse, mutect2, varscan2
- SPATC1 | c.1188G>A p.P396= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs138355309; called by muse, mutect2, varscan2
- STAP1 | c.423C>A p.V141= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV55327371; called by muse, mutect2
- TMEM61 | c.333C>T p.L111= | Silent (SNP) | VAF 11/125 reads (9%) | catalogued as COSV64873514; called by muse, mutect2
- TMEM62 | c.1176C>T p.I392= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs147758442, COSV53040884; called by muse, mutect2, varscan2
- TMEM71 | c.96C>T p.F32= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV63457167; called by muse, mutect2, varscan2
- TRIM42 | c.1713C>G p.L571= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV99648368; called by muse, mutect2
- TTC17 | c.2068C>T p.L690= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV50007929; called by muse, mutect2, varscan2
- UNC13A | c.2589C>T p.D863= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs765086018, COSV53193647; called by muse, mutect2, varscan2
- WDR26 | c.1782G>A p.L594= (on ENST00000414423 / NM_001379403.1; = p.L494= on NM_025160.7) | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as rs143580897; called by muse, mutect2
- XIRP2 | c.6612C>T p.L2204= (on ENST00000628543; = p.L2379= on NM_152381.6) | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1477776429, COSV54695470; called by muse, mutect2, varscan2
- ZNF175 | c.621G>C p.L207= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV51797314, COSV99219513; called by muse, mutect2
- RNU7-174P | chr8:80559121 G>A | 5'Flank (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1280G>T | 3'UTR (SNP) | VAF 11/25 reads (44%) | catalogued as rs756637989, COSV99743031; called by muse, mutect2, varscan2
- ZNF467 | chr7:149776993 ins G | 5'Flank (INS) | VAF 10/42 reads (24%) | catalogued as rs748030684; called by mutect2, varscan2
